Surgical pathology report (de-identified scan), TCGA case TCGA-06-0240, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0240-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

MRN:

Sex: Male Room/Bed:

Patient Name:

DOB:
ClierAccession #:
Phone Number:
Gender: M
Locati
Taken:
Received:
Reported:

Physician(s):

Phy Location:

=====

CLINICAL HISTORY

year-old man had biopsy diagnosis of a superior temporal brain tumor as GBM. For gross total resection.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain tumor, biopsy
B: Brain, excision biopsy
C: Brain, excision biopsy

P. OLOGICAL DIAGNOSIS:

A. Brain, site not specified, biopsy: Cerebral cortex, not diagnostic.
B and C. Brain, site not specified, excision: Glioblastoma.
See Comment.

COMMENT

Part A is a portion of cerebral cortex in which there is a handful of isolated naked nuclei that may correspond to neoplastic astrocytes or to activated microglia.

Parts B and C contain a neoplastic astrocytic proliferation that diffusely infiltrates and focally effaces the cerebrum. The neoplastic cells are small, and have an astrocyte phenotype. There are brisk mitotic activity, microvascular cellular proliferation, and zones of necrosis, some with pseudopalisading.

Special stains to better characterize the neoplasm have been requested and will be reported as an addendum.

Electronically Signed Out

=====

PROCEDURES/ADDENDA

Immunohistology

Interpretation

Brain, Immunohistochemistry, MIB-1 proliferation index: 40%.
See Results and Comment.

[page 2 of 3]
Patient Name:

MRN:

Sex: Male Room/Bed:

Results-Comments

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates glial fibrillogenesis by the neoplastic cells. Only about 1% of the cells over express, weakly, the p53 protein. The CD34 depicts the rich vascularity of the tumor and prominent microvascular cellular proliferation. With the MIB-1 there is a proliferation index of about 40% throughout the tumor.

Comment: The immuno results are consistent with a high histological grade astrocytic neoplasm.

Electronically Signed Out

MGMT Promoter Methylation

Interpretation

NEGATIVE - No evidence of methylated MGMT promoter is detected.

Results-Comments

Received were paraffin curls labeled

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the FDA as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

=====

INTRA-OPERATIVE CONSULTATION

A. Brain tumor, biopsy, smears and touch prep: Cerebral cortex, not diagnostic.

B. Brain, tumor, touch prep and smears: Glioblastoma.

GROSS DESCRIPTION

A. Received fresh, one fragment, 0.6-cm. across. Cerebral cortex and tiny portion of white matter. In total, A1.

B.

[page 3 of 3]
Patient Name:

MRN:

Sex: Male Room/Bed:

Received fresh, one fragment, 0.8 x 0.3-cm. Semi firm, fibrillary, grayish-blue, glistening. In total, B.

C.

SPECIMEN: Brain, excision biopsy:

FIXATIVE: None.

GENERAL: A 2 x 1 x 0.5 cm. tan-red gelatinous focally hemorrhagic tissue fragment.

SECTIONS: Serially sectioned and entirely submitted in two cassettes.

ICD-9(s):

191.2 191.2

Histo Data

Part A: Brain tumor, biopsy

Stain/	Block	Ordered	Comment
H/E x 1	1		

Part B: Brain, excision biopsy

Taken:	Received:		
Stain/	Block	Ordered	Comment
H/E x 1	1		

Part C: Brain, excision biopsy

Taken:	Received:		
Stain/	Block	Ordered	Comment
H/E x 1	1		
CD34-DA x 1	2		
mGFAP-DA x 1	2		
H/E x 1	2		
mGFAP x 1	2		
MIB1-DA x 1	2		
P53DO7 x 1	2		

*** End of Report ***

Source: NCI Genomic Data Commons file 7abf5635-485b-4414-83d8-66e4db41c7de (TCGA-06-0240.572A468C-EF7B-407B-8D56-9CDED6A1BBDF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).